Somatic mutation profile of tumor specimen TCGA-DY-A1DG-01A (aliquot TCGA-DY-A1DG-01A-11D-A152-10) from TCGA case TCGA-DY-A1DG, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Age at diagnosis: 75.0 years (27,396 days).
Specimen TCGA-DY-A1DG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aea92ce9-c6bd-4f6e-be05-a4bff7c5c415.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DY-A1DG-10A (Blood Derived Normal), aliquot TCGA-DY-A1DG-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27665ffe-aa27-4ffc-945a-f4d54b111664

The open-access MAF lists 183 somatic variants for this specimen: 135 protein-altering or splice-affecting, 45 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 45, Nonsense Mutation 7, In Frame Del 2, Frame Shift Ins 1, RNA 1, Frame Shift Del 1, In Frame Ins 1, Intron 1, 5'Flank 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 78/90 reads (87%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYSF | c.3307A>T p.K1103* | Nonsense Mutation (SNP) | VAF 23/129 reads (18%) | catalogued as rs1558513494, CM066054, COSV50487393; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.4259G>T p.C1420F | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs397515804, CD145774, CM098690, CM127496, COSV57324469; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 27/27 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACBD5 | c.1487C>A p.P496Q (on ENST00000375888 / NM_001352568.1; = p.P487Q on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV65518817; called by muse, mutect2, varscan2
- ACTL7A | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV100453130; called by muse, varscan2
- ALMS1 | c.2791G>T p.A931S | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.81); catalogued as COSV52515955; called by muse, mutect2, varscan2
- ALOX12B | c.1654+1G>T p.X552_splice | Splice Site (SNP) | VAF 19/33 reads (58%) | catalogued as COSV59874686; called by muse, mutect2, varscan2
- ASPH | c.2218G>A p.V740M | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762826838, COSV57974483; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1919G>A p.G640D | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV57750783; called by muse, mutect2, varscan2
- AWAT2 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs762323805, COSV52142983, COSV52144009; called by muse, mutect2, varscan2
- BCL9 | c.2690C>T p.A897V | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs782580573, COSV52347700; called by muse, mutect2, varscan2
- BRPF1 | c.1225T>A p.F409I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57406587; called by muse, mutect2, varscan2
- CATSPERG | c.3296C>T p.T1099M | Missense Mutation (SNP) | VAF 181/206 reads (88%) | SIFT tolerated (0.14); PolyPhen benign (0.364); catalogued as rs768674555, COSV53048282; called by muse, mutect2, varscan2
- CCDC91 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs544457452, COSV60339285; called by muse, mutect2, varscan2
- CD207 | c.967T>G p.Y323D | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV69652399; called by muse, mutect2, varscan2
- CD44 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53530362; called by muse, mutect2, varscan2
- CD83 | c.405A>T p.E135D | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as COSV64788483; called by muse, mutect2, varscan2
- CDSN | c.325G>T p.G109* | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | catalogued as COSV52539054, COSV52540249; called by muse, mutect2, varscan2
- CHRNA6 | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200478711, COSV52379382; called by muse, mutect2, varscan2
- CLEC16A | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 76/123 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.356); catalogued as rs201942249, COSV68500963; called by muse, mutect2, varscan2
- CNPPD1 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs200203236, COSV99841192; called by muse, mutect2
- CORO6 | c.450A>T p.A150= | Splice Region (SNP) | VAF 15/83 reads (18%) | catalogued as COSV61471517; called by muse, mutect2, varscan2
- CPED1 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV59999256; called by muse, mutect2, varscan2
- CPNE4 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as rs778013344, COSV70197363; called by mutect2, varscan2
- CRNKL1 | c.710A>G p.K237R | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.02); catalogued as COSV99845240; called by muse, mutect2, varscan2
- CTNNA2 | c.2800C>A p.Q934K (on ENST00000402739 / NM_001282597.3; = p.Q886K on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.258); catalogued as COSV58152011, COSV58165937; called by muse, mutect2, varscan2
- DISP3 | c.1166A>T p.N389I | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV53833100; called by muse, mutect2, varscan2
- DNAH5 | c.6407C>T p.T2136M | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as rs140690090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC16 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.517); catalogued as COSV65449093; called by muse, mutect2, varscan2
- DNPEP | c.1214C>A p.A405D | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56111353, COSV99815228; called by muse, mutect2
- ERBB4 | c.620C>G p.T207S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99625177; called by muse, mutect2, varscan2
- F13B | c.1663G>C p.D555H | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100803312; called by muse, mutect2, varscan2
- FAAH2 | c.1237T>A p.L413M | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.574); catalogued as COSV66510159; called by muse, mutect2, varscan2
- FAM160A2 | c.2773G>T p.V925F (on ENST00000449352 / NM_001098794.2; = p.V939F on NM_032127.4) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56413118, COSV99791771; called by muse, mutect2, varscan2
- FAM221B | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV100941272, COSV65074820; called by muse, mutect2, varscan2
- FARP1 | c.2889C>G p.F963L | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60342745; called by muse, mutect2, varscan2
- FBXW10 | c.2602G>C p.D868H | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100111503; called by muse, mutect2, varscan2
- GNG3 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53655372; called by muse, mutect2, varscan2
- GOLGA4 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1037140742, COSV62712268; called by muse, mutect2, varscan2
- GPNMB | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs776093177, COSV51697161; called by muse, mutect2, varscan2
- GPR37 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.182); catalogued as rs1269676678, COSV58258405; called by muse, mutect2, varscan2
- GUCA2B | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs377375076; called by muse, mutect2, varscan2
- GUF1 | c.13G>C p.V5L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs752759099, COSV55783827; called by muse, mutect2, varscan2
- HACE1 | c.236A>T p.E79V | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1380681749, COSV53505011; called by muse, mutect2, varscan2
- HAS3 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54708262; called by muse, mutect2, varscan2
- HELQ | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.083); catalogued as COSV55025125; called by muse, mutect2, varscan2
- HSPA12A | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs555217651, COSV65022479; called by muse, mutect2, varscan2
- IGKV1-8 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs747535306; called by muse, mutect2, varscan2
- IKZF3 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV53101083, COSV53101917, COSV53104568; called by muse, mutect2, varscan2
- INTS4 | c.2488G>C p.E830Q | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as rs1044911, COSV59019596, COSV59019914; called by muse, mutect2, varscan2
- JHY | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56217831; called by muse, mutect2, varscan2
- KALRN | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53773466; called by muse, mutect2, varscan2
- KDM3B | c.2798C>T p.S933F | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100069770; called by muse, mutect2, varscan2
- KRIT1 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60669384; called by muse, mutect2
- KRT24 | c.1014G>T p.K338N | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV52880423, COSV52881064; called by muse, mutect2, varscan2
- KRTAP5-7 | c.137G>A p.C46Y | Missense Mutation (SNP) | VAF 67/244 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs1320791047, COSV68325471; called by muse, mutect2, varscan2
- LCTL | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100328720; called by muse, mutect2, varscan2
- LEPR | c.2149A>T p.I717F | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.475); catalogued as COSV60759631; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs970324833, COSV53276741, COSV53283364; called by muse, mutect2, varscan2
- LRP1B | c.11253T>A p.C3751* | Nonsense Mutation (SNP) | VAF 33/132 reads (25%) | catalogued as COSV101257739; called by muse, mutect2, varscan2
- LRRC7 | c.240T>A p.F80L (on ENST00000651989 / NM_001370785.2; = p.F47L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV50521669; called by muse, mutect2, varscan2
- MAGIX | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 139/142 reads (98%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs1185625654, COSV100891877, COSV66255692; called by muse, mutect2, varscan2
- MCF2L | c.487G>A p.V163I (on ENST00000375608; = p.V131I on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.942); catalogued as rs763446044, COSV65052183; called by mutect2, varscan2
- MCM7 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1396825913, COSV57995395; called by muse, mutect2, varscan2
- MR1 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.203); catalogued as COSV51581507; called by muse, mutect2, varscan2
- NCK2 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1382749200, COSV51893712; called by muse, mutect2, varscan2
- NCKAP5 | c.4373C>T p.A1458V | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs112873686; called by muse, mutect2, varscan2
- NEB | c.5594C>T p.S1865F | Missense Mutation (SNP) | VAF 17/343 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV51438048; called by muse, mutect2
- NHSL2 | c.623G>T p.S208I (on ENST00000510661; = p.S574I on NM_001013627.2) | Missense Mutation (SNP) | VAF 37/39 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65454228; called by muse, mutect2, varscan2
- NOP2 | c.510G>C p.K170N (on ENST00000322166 / NM_001258308.2; = p.K166N on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV59112312; called by muse, mutect2, varscan2
- NOS3 | c.1435C>A p.P479T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52492814; called by muse, mutect2, varscan2
- OAS1 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.305); catalogued as COSV52537494; called by muse, mutect2, varscan2
- ODAM | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 121/213 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as rs1247337791, COSV68573194; called by muse, mutect2, varscan2
- OLA1 | c.919T>C p.Y307H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as COSV52972281; called by muse, mutect2, varscan2
- OR10G7 | c.11C>G p.A4G | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100389959; called by muse, varscan2
- OR5M8 | c.503G>T p.C168F | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59117544; called by muse, mutect2, varscan2
- OSTC | c.437A>G p.Y146C | Missense Mutation (SNP) | VAF 26/649 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs959437976, COSV100843205; called by muse, mutect2
- OTOP1 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.019); catalogued as COSV56395121; called by muse, mutect2, varscan2
- OVCH1 | c.1391A>G p.D464G | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV58965822; called by muse, mutect2, varscan2
- PABPN1 | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 48/53 reads (91%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs1421864106, COSV53729079, COSV53729967; called by muse, mutect2, varscan2
- PLG | c.1330G>A p.V444I | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs574500945, COSV51981136; called by muse, mutect2, varscan2
- POU5F1 | c.881_883del p.Q294del | In Frame Del (DEL) | VAF 49/316 reads (16%) | catalogued as rs765569430; called by mutect2, pindel, varscan2
- PRKAB1 | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.147); catalogued as COSV57555323; called by muse, mutect2, varscan2
- PRRC2A | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs755147720, COSV63224878; called by muse, mutect2, varscan2
- PTPRD | c.3369G>A p.M1123I | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs781290016, COSV61950407, COSV61965604; called by muse, mutect2, varscan2
- PVR | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 76/259 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.346); catalogued as rs777036330, COSV51822351; called by muse, mutect2, varscan2
- PYCARD | c.340T>G p.F114V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs899871787, COSV99910935; called by muse, mutect2, varscan2
- RAB5A | c.268T>A p.Y90N | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56085151; called by muse, mutect2
- RADIL | c.2059G>A p.G687R | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375439747; called by muse, mutect2, varscan2
- RHBDL3 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.876); catalogued as rs201683603, COSV52185093, COSV52187806; called by muse, mutect2, varscan2
- RTL5 | c.1324C>A p.P442T | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.305); catalogued as COSV65454220; called by muse, mutect2, varscan2
- RYR1 | c.9845C>A p.P3282H | Missense Mutation (SNP) | VAF 82/84 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV62103891; called by muse, mutect2, varscan2
- SIGLEC6 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1224241402, COSV58434515; called by muse, mutect2, varscan2
- SLAMF8 | c.110C>A p.A37E | Missense Mutation (SNP) | VAF 64/92 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56989325; called by muse, mutect2, varscan2
- SLC13A3 | c.1525C>A p.L509M | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV51717742; called by muse, varscan2
- SLC18A3 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.03); catalogued as COSV60329106; called by muse, mutect2, varscan2
- SLC5A3 | c.1453T>A p.L485M | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV62971750; called by muse, mutect2, varscan2
- SLC9C1 | c.2660A>G p.K887R | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV59890544; called by muse, mutect2, varscan2
- SLITRK4 | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 68/70 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62025270; called by muse, mutect2, varscan2
- SLITRK6 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs747849108, COSV68390960; called by muse, mutect2, varscan2
- SMG7 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 85/135 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs763270668, COSV61632912; called by muse, mutect2, varscan2
- SOX7 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747827752, COSV58731279; called by muse, mutect2, varscan2
- SPRR1B | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV100198385, COSV61067900; called by muse, mutect2, varscan2
- ST8SIA2 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 15/49 reads (31%) | PolyPhen probably damaging (1); catalogued as COSV51571289; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2650C>G p.L884V | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs1195548892, COSV59134434; called by muse, mutect2, varscan2
- TACC2 | c.6229C>T p.P2077S (on ENST00000334433; = p.P155S on NM_006997.4) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV53285866; called by muse, mutect2, varscan2
- TAF1L | c.4109C>T p.P1370L | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as rs746620042, COSV54265416; called by muse, mutect2, varscan2
- TBC1D3B | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.244); catalogued as rs1330136710; called by muse, mutect2, varscan2
- TCF7L2 | c.809C>T p.P270L (on ENST00000355995 / NM_001367943.1; = p.P247L on NM_030756.5) | Missense Mutation (SNP) | VAF 125/201 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV53344997; called by muse, mutect2, varscan2
- TMEM132D | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs542855447, COSV67158848; called by muse, mutect2, varscan2
- TMEM198 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 72/111 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1349360573, COSV54725543; called by muse, mutect2, varscan2
- TOE1 | c.515C>A p.S172* | Nonsense Mutation (SNP) | VAF 29/95 reads (31%) | catalogued as COSV59155243; called by muse, mutect2, varscan2
- TRRAP | c.5786C>T p.P1929L (on ENST00000359863 / NM_001244580.1; = p.P1911L on NM_003496.3) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62838259; called by muse, mutect2, varscan2
- TTN | c.71396A>G p.Y23799C (on ENST00000591111; = p.Y16375C on NM_003319.4) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | PolyPhen probably damaging (0.999); catalogued as COSV60202471; called by muse, mutect2, varscan2
- UBASH3B | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as rs777116957, COSV52493647; called by muse, mutect2, varscan2
- UBE3A | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV51668532; called by muse, mutect2, varscan2
- UMOD | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs767780614, COSV56777798; called by muse, mutect2, varscan2
- VAX2 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs145503713; called by muse, mutect2, varscan2
- WDPCP | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV55426457; called by muse, mutect2, varscan2
- WRN | c.3492G>T p.R1164S | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99989185; called by muse, mutect2
- XIRP2 | c.1427T>C p.V476A (on ENST00000628543; = p.V651A on NM_152381.6) | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54718349; called by muse, mutect2, varscan2
- ZFAT | c.3367C>T p.R1123* | Nonsense Mutation (SNP) | VAF 57/76 reads (75%) | catalogued as rs200421725, COSV64740286; called by muse, mutect2, varscan2
- ZFR | c.3080A>T p.H1027L | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV99416080; called by muse, mutect2, varscan2
- ZNF396 | c.47C>A p.S16* | Nonsense Mutation (SNP) | VAF 29/31 reads (94%) | catalogued as COSV60473666, COSV60474650; called by muse, mutect2, varscan2
- ZNF488 | c.694A>C p.T232P | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs782596702; called by muse, mutect2, varscan2
- ZNF577 | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV100031082, COSV56815007; called by muse, mutect2
- ZNF667 | c.914G>C p.G305A | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.43); catalogued as COSV52637115; called by muse, mutect2, varscan2
- ZNF99 | c.1103C>A p.P368H | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV68056160; called by muse, mutect2, varscan2
- ADARB2 | c.1985del p.G662Afs*21 | Frame Shift Del (DEL) | VAF 66/119 reads (55%) | called by mutect2, pindel, varscan2
- ARHGAP5 | c.1115_1135del p.A372_F378del | In Frame Del (DEL) | VAF 28/74 reads (38%) | called by mutect2, pindel, varscan2
- ATP8B4 | c.824_826dup p.T275_L276insP | In Frame Ins (INS) | VAF 15/54 reads (28%) | called by mutect2, pindel, varscan2
- IKBKG | c.506C>A p.A169D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TEX15 | c.4556A>T p.K1519I (on ENST00000256246; = p.K1902I on NM_001350162.2) | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2
- USP19 | c.3744dup p.Q1249Afs*6 | Frame Shift Ins (INS) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- ADAMTS14 | c.189C>T p.A63= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1316888921, COSV100941635; called by muse, mutect2
- ANKRD12 | c.996C>T p.D332= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as rs773821570, COSV50835816; called by muse, mutect2, varscan2
- ARID5B | c.3291T>C p.A1097= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99689806; called by muse, mutect2, varscan2
- ASTN1 | c.3441G>A p.V1147= | Silent (SNP) | VAF 31/125 reads (25%) | catalogued as COSV62501182; called by muse, mutect2, varscan2
- CACNA1G | c.4755G>A p.A1585= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs780560019, COSV61732721; called by muse, mutect2, varscan2
- CCDC27 | c.1599C>T p.V533= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV53901954; called by muse, mutect2, varscan2
- CSF2RA | c.429G>A p.T143= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs368476257, COSV62623904; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAAH2 | c.1236T>A p.A412= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV66510153; called by muse, mutect2, varscan2
- FBXO44 | c.558G>A p.A186= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs376358727; called by muse, mutect2, varscan2
- GJA3 | c.1038G>A p.A346= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99576405; called by muse, mutect2
- GRID1 | c.1602G>A p.K534= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV60041720; called by muse, mutect2, varscan2
- GTDC1 | c.753G>A p.S251= | Silent (SNP) | VAF 79/259 reads (31%) | catalogued as rs867258588, COSV54000512; called by muse, mutect2, varscan2
- HDAC2 | c.348C>T p.G116= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as rs373430125; called by muse, mutect2, varscan2
- HOATZ | c.390A>G p.E130= (on ENST00000375618 / NM_001100388.1; = p.E157= on NM_207430.2) | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV60441977; called by muse, mutect2, varscan2
- IFNAR1 | c.915C>G p.L305= | Silent (SNP) | VAF 123/269 reads (46%) | catalogued as COSV54253336; called by muse, mutect2, varscan2
- IQGAP3 | c.1134C>T p.L378= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs1266545911, COSV100752173; called by muse, varscan2
- IRX6 | c.1167C>T p.A389= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs762901105, COSV51861376; called by muse, mutect2, varscan2
- LIMK2 | c.1254C>T p.R418= | Silent (SNP) | VAF 15/20 reads (75%) | catalogued as COSV59183422; called by muse, mutect2, varscan2
- LINGO1 | c.159C>T p.R53= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs763677952, COSV62437792; called by muse, mutect2, varscan2
- LRIT1 | c.1329C>T p.S443= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs1460154968, COSV64513225, COSV64513969; called by muse, mutect2, varscan2
- LYPLA2 | c.243G>A p.L81= | Silent (SNP) | VAF 58/233 reads (25%) | catalogued as COSV65720828; called by muse, mutect2, varscan2
- MYO15A | c.1545C>T p.D515= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV52754669; called by muse, mutect2, varscan2
- NFE2L2 | c.213C>T p.F71= | Silent (SNP) | VAF 122/236 reads (52%) | catalogued as rs775813661, COSV67961742; called by muse, mutect2, varscan2
- NKD2 | c.1353C>G p.S451= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV99724152; called by muse, mutect2
- NLRP2 | c.915C>T p.C305= | Silent (SNP) | VAF 34/38 reads (89%) | catalogued as rs370946962; called by muse, mutect2, varscan2
- NR2E3 | c.999G>A p.T333= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs772856819, COSV100489449; called by muse, mutect2, varscan2
- NUP214 | c.4101C>T p.G1367= | Silent (SNP) | VAF 50/133 reads (38%) | catalogued as rs755825772, COSV63911410, COSV63913058; called by muse, mutect2, varscan2
- OR5H1 | c.186C>A p.L62= | Silent (SNP) | VAF 180/687 reads (26%) | catalogued as COSV100641717; called by muse, mutect2, varscan2
- PCDHA13 | c.1611G>A p.A537= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV56527193; called by muse, mutect2, varscan2
- PCDHA7 | c.1434G>A p.S478= | Silent (SNP) | VAF 144/158 reads (91%) | catalogued as COSV65345956; called by muse, mutect2, varscan2
- PCDHA8 | c.1410G>A p.P470= | Silent (SNP) | VAF 173/182 reads (95%) | catalogued as rs202126810, COSV65334668, COSV65339563; called by muse, mutect2, varscan2
- PLEKHA4 | c.402C>T p.A134= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV54364657; called by muse, mutect2, varscan2
- PRDM14 | c.54G>A p.P18= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV52573930; called by muse, mutect2, varscan2
- PRPF19 | c.936C>T p.L312= | Silent (SNP) | VAF 63/67 reads (94%) | catalogued as COSV57128695; called by muse, mutect2, varscan2
- PRUNE2 | c.6198C>T p.A2066= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs372544904; called by muse, mutect2, varscan2
- RAB11FIP3 | c.975C>T p.D325= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs184050293, COSV51935845; called by muse, mutect2, varscan2
- RAB6B | c.105C>T p.Y35= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs772849485, COSV53311826; called by muse, mutect2, varscan2
- RBP3 | c.201G>A p.P67= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs782052263; called by muse, mutect2, varscan2
- SBK2 | c.525C>T p.H175= | Silent (SNP) | VAF 26/30 reads (87%) | catalogued as rs1376397729, COSV60015073; called by muse, mutect2, varscan2
- SPTAN1 | c.6639C>T p.H2213= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs372825476; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- STRN4 | c.1476C>T p.G492= | Silent (SNP) | VAF 54/58 reads (93%) | catalogued as COSV99623715; called by muse, varscan2
- TAF1L | c.9C>T p.P3= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as rs938277242, COSV54260176; called by muse, mutect2, varscan2
- TAT | c.69C>T p.N23= | Silent (SNP) | VAF 26/166 reads (16%) | catalogued as rs370850249; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZFPM1 | c.561C>T p.S187= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV60323968; called by muse, mutect2, varscan2
- ZNF699 | c.1119C>T p.S373= | Silent (SNP) | VAF 31/35 reads (89%) | catalogued as rs771715386, COSV58025517; called by muse, mutect2, varscan2
- FAM183BP | n.1121C>T | RNA (SNP) | VAF 36/117 reads (31%) | catalogued as rs779795402; called by muse, mutect2, varscan2
- GCSH | chr16:81101258 A>T | 5'Flank (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- TPM1 | c.115-274G>A | Intron (SNP) | VAF 6/24 reads (25%) | catalogued as COSV51264045; called by muse, mutect2, varscan2
